CCDI case PBBPTC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/3a45c0bf-4f55-455b-9c9b-4c2bc23953a8

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Myofibroma: ICD-O-3 morphology code: 8824/0; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 0.7 years (261 days).

Biospecimens (3 samples)
- Sample 0DEJZ4: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DEK19: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DEK1N: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
